Somatic mutation profile of tumor specimen MP2PRT-PATELX-TMP1-A (aliquot MP2PRT-PATELX-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PATELX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,678 days).
Specimen MP2PRT-PATELX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2df058a5-bf86-422b-9b29-efc013c6d40b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATELX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATELX-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2593a3b6-f26a-485c-a5e5-d72d1c227c63

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYZL1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 36/550 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs766725731, COSV64966156; called by muse, mutect2
- MRPL16 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 35/430 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1359217474, COSV55697625; called by muse, mutect2
- SATB2 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 51/459 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as COSV53484665; called by muse, mutect2, varscan2
- CCDC185 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ME3 | c.240G>A p.P80= | Silent (SNP) | VAF 38/486 reads (8%) | catalogued as rs538087697; called by muse, mutect2
- STOX2 | c.123G>A p.Q41= | Silent (SNP) | VAF 49/930 reads (5%) | called by muse, mutect2
